CCDI case PBBZEB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/099f7cbf-4e25-4fc5-80ea-18ac02dd2f29

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Schwannoma, NOS: ICD-O-3 morphology code: 9560/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,628 days).

Biospecimens (3 samples)
- Sample 0DLDZC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLDZI: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLDZK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
